Surgical pathology report (de-identified scan), TCGA case TCGA-K4-A54R, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-K4-A54R-01A (Primary Tumor).

[page 1 of 7]
Name
Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Correction

Source of Specimen

- A. LEFT DISTAL URETER MARGIN FS-
- B. RIGHT DISTAL URETER MARGIN FS-
- C. DISTAL URETHRAL MARGIN OF RADICAL CYSTECTOMY SPECIMEN FS-
- D. LEFT PELVIC LYMPH NODE-
- E. RIGHT PELVIC LYMPH NODE-
- F. BLADDER AND PROSTATE GLAND, SEMINAL VESICLES-

Reason for Correction

TO CORRECT TYPOGRAPHICAL ERROR.

1CD-0-3

carcinoma, urothelial, NOS 8/20/3
Site: bladder, dome C 67.1

FINAL DIAGNOSIS:

- A. LEFT DISTAL URETER MARGIN FS-
SEGMENT OF URETER, NO TUMOR SEEN.
- B. RIGHT DISTAL URETER MARGIN FS-
SEGMENT OF URETER, NO TUMOR SEEN.
- C. DISTAL URETHRAL MARGIN OF RADICAL CYSTECTOMY SPECIMEN FS-
NO TUMOR SEEN IN URETHRAL MUCOSA.

fw
12/3/12

PROSTATE TISSUE, SEE SPECIMEN "F".

- D. LEFT PELVIC LYMPH NODE-
FOUR LYMPH NODES, NO TUMOR SEEN.
- E. RIGHT PELVIC LYMPH NODE-
FOUR LYMPH NODES, NO TUMOR SEEN.
- F. BLADDER AND PROSTATE GLAND, SEMINAL VESICLES-

INVASIVE CARCINOMA, HIGH GRADE.

TUMOR SITE: DOME, URINARY BLADDER.

Prepared

[page 2 of 7]
HISTOLOGIC TYPE: UROTHELIAL.

SQUAMOUS DIFFERENTIATION: IS PRESENT.

GLANDULAR DIFFERENTIATION: IS NOT PRESENT.

TUMOR SIZE: 2.5 CM.

HISTOLOGIC GRADE: 3/3.

DEPTH OF INVASION: DEEP PORTION OF MUSCULARIS PROPRIA.

SPECIMEN TYPE: CYSTECTOMY/PROSTATECTOMY

TNM STAGE: pT2b, pN0, pMX.

(T2a: inner half; T2b, outer half)

(N1, single pelvic node; N2, multiple pelvic nodes; N3, common iliac node)

LYMPH NODE(S) INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 8

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

ASSOCIATED EPITHELIAL LESIONS: IDENTIFIED.

NO TUMOR SEEN AT MARGIN(S).

PROSTATE ADENOCARCINOMA, GLEASON 3+3=6/10

ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: BILATERAL, APEX AND PERIPHERAL ZONES

SPECIMEN TYPE: CYSTOPROSTATECTOMY

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: NOT PRESENT.

SEVERITY IN EXTENT OF TUMOR: 1 /5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): NOT PRESENT.

Prepared for

[page 3 of 7]
TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: pT2c, pN0, pMX.

(T2a = one side, < 50%; T2b = one side, > 50%; T2c = bilateral)

(N0: negative node; N1: positive regional node)

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

PERINEURAL INVASION: NOT PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

[REDACTED]

Signed Others

Frozen Section

A. RIGHT DISTAL URETER- NO TUMOR SEEN.

LEFT DISTAL URETER- NO TUMOR SEEN.

DISTAL URETHRAL MARGIN FROM RADICAL CYSTECTOMY- NO TUMOR SEEN.

[REDACTED]

Case Clinical Information

MUSCLE INVASIVE TRANSITIONAL CELL CARCINOMA OF BLADDER

Gross Description

A. Received in formalin labeled with the patient's name and "left distal ureter margin-FS" is a 0.7 cm frozen section tissue remnant with a pinpoint lumen identified. Wrapped and entirely submitted in A1.

B. Received in formalin labeled with the patient's name and "right distal ureter margin-FS" is a 0.8 cm frozen section tissue remnant with a pinpoint lumen identified. Wrapped and entirely submitted in B1.

C. Received in formalin labeled with the patient's name and "distal urethral margin of radical cystectomy specimen-FS" is a

Prepared for [REDACTED]

[page 4 of 7]
3 x 2 x 0.5 cm thick frozen section tissue remnant. Entirely submitted in C1.

D. Received in formalin labeled with the patient's name and "left pelvic lymph node" are four nodules of tan adipose tissue consistent with lymphoid tissue ranging in size from 2 cm down to 1.5 cm. The excess fat is trimmed. All four nodes are submitted entirely as follows: D1= one lymph node bisected; D2= one lymph node bisected; D3-D4= one lymph node bisected; D5-D6= one lymph node bisected.

E. Received in formalin labeled with the patient's name and "right pelvic lymph node" are four nodules of tan fatty tissue. All four nodules are submitted as follows: E1-E2= one lymph node bisected; E3= one single lymph node; E4= one single lymph node; E5-E6= one lymph node bisected.

F. Received in formalin labeled with the patient's name and "bladder, prostate gland and seminal vesicles" is a radical cystectomy specimen with attached fat measuring 16 x 11 x 7 cm. The attached prostate measures 4.5 x 4 x 4 cm. A 3 cm defect is identified on the prostatic urethral margin. This is grossly consistent with tissue taken for frozen section evaluation. The specimen is inked black on the left and blue on the right. The right seminal vesicle measures 5 x 1 x 1 cm. The right vas deferens measures 7 cm in length. The left seminal vesicle measures 5 x 1 x 1 cm. The left vas deferens measures 11 cm in length. The left and right ureters are embedded in the fat and have been previously taken for frozen section evaluation. The bladder is opened anteriorly and in the dome of the bladder a circumscribed tan, friable mass is identified measuring 2.4 x 2 x 1 cm. The remainder of the bladder mucosa has a retracted cobble-stoned appearance. No additional gross tumor is identified. The cut surface of the mass has a very friable tan glistening appearance and grossly appears to have invaded into the muscularis. The posterior bladder all on cut surface is grossly unremarkable. The left and right lateral bladder walls are serially sectioned and are grossly unremarkable. The right side of the prostate is serially sectioned to reveal a focally nodular tan-pink grossly unremarkable parenchyma. The left prostate is serially sectioned and in the lower one third the parenchyma reveals a 1 cm cyst that is lined with a smooth tissue. The lumen contains a clear fluid. Representative sections of the specimen are submitted as follows: F1-F3= mass at dome on right side; F4-F6= mass at dome on left side; F7-F8= right posterior wall; F9-F10= left posterior wall; F11-F13= right lateral wall; F14-F16= left lateral wall; F17= right trigone; F18= left trigone; F19-F21= representative sections of upper, mid and lower one third of prostate, right side; F22-F24= representative sections of upper, mid and lower one third of prostate, left side. Also, F24 demonstrates cystic structure on left side of prostate previously described. Additional sections

Prepared by

[page 5 of 7]
submitted as follows: F25-F27= additional full thickness cross sections of prostate upper, mid and lower one third right side; F28-F30= representative sections of upper, mid and lower one third of prostate left side.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- D. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.5

Prepared for

[page 6 of 7]
H&E X1
F. AA ROUTINE H&E X1 BLOCK.6
H&E X1
F. AA ROUTINE H&E X1 BLOCK.7
H&E X1
F. AA ROUTINE H&E X1 BLOCK.8
H&E X1
F. AA ROUTINE H&E X1 BLOCK.9
H&E X1
F. AA ROUTINE H&E X1 BLOCK.10
H&E X1
F. AA ROUTINE H&E X1 BLOCK.11
H&E X1
F. AA ROUTINE H&E X1 BLOCK.12
H&E X1
F. AA ROUTINE H&E X1 BLOCK.13
H&E X1
F. AA ROUTINE H&E X1 BLOCK.14
H&E X1
F. AA ROUTINE H&E X1 BLOCK.15
H&E X1
F. AA ROUTINE H&E X1 BLOCK.16
H&E X1
F. AA ROUTINE H&E X1 BLOCK.17
H&E X1
F. AA ROUTINE H&E X1 BLOCK.18
H&E X1
F. AA ROUTINE H&E X1 BLOCK.19
H&E X1
F. AA ROUTINE H&E X1 BLOCK.20
H&E X1
F. AA ROUTINE H&E X1 BLOCK.21
H&E X1
F. AA ROUTINE H&E X1 BLOCK.22
H&E X1
F. AA ROUTINE H&E X1 BLOCK.23
H&E X1
F. AA ROUTINE H&E X1 BLOCK.24
H&E X1
F. AA ROUTINE H&E X1 BLOCK.25
H&E X1
F. AA ROUTINE H&E X1 BLOCK.26
H&E X1
F. AA ROUTINE H&E X1 BLOCK.27
H&E X1
F. AA ROUTINE H&E X1 BLOCK.28
H&E X1
F. AA ROUTINE H&E X1 BLOCK.29
H&E X1

Prepared

[page 7 of 7]
F. AA ROUTINE H&E X1 BLOCK.30
H&E X1

Prepared

12/31/12

Source: NCI Genomic Data Commons file ff17f160-d4b2-46d6-8f47-dd3f559e9205 (TCGA-K4-A54R.176B5C21-B423-41BE-AFAB-565E58E5404C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).